Somatic mutation profile of tumor specimen TCGA-EI-6513-01A (aliquot TCGA-EI-6513-01A-21D-1733-10) from TCGA case TCGA-EI-6513, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma in tubulovillous adenoma; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 59.6 years (21,776 days).
Specimen TCGA-EI-6513-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 81c817cc-d76d-49b8-ba93-500990f93baf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EI-6513-10A (Blood Derived Normal), aliquot TCGA-EI-6513-10A-01D-1733-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1397a095-bb17-48b0-8d55-625e25133822

The open-access MAF lists 143 somatic variants for this specimen: 114 protein-altering or splice-affecting, 26 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 100, Silent 26, Frame Shift Ins 4, In Frame Del 3, Nonsense Mutation 3, Splice Site 2, Splice Region 1, Translation Start Site 1, RNA 1, 5'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP8B1 | c.614dup p.N205Kfs*2 | Frame Shift Ins (INS) | VAF 48/79 reads (61%) | catalogued as rs761784230; ClinVar: pathogenic; called by mutect2, varscan2
- ADAMTS12 | c.308T>G p.F103C | Missense Mutation (SNP) | VAF 37/102 reads (36%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.95); catalogued as COSV61266675; called by muse, mutect2, varscan2
- ANAPC7 | c.203+1G>T p.X68_splice | Splice Site (SNP) | VAF 19/55 reads (35%) | catalogued as rs111908272, COSV71443871; called by muse, mutect2, varscan2
- ANKMY1 | c.1618C>T p.P540S | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.554); catalogued as COSV56036302; called by muse, mutect2, varscan2
- APOL1 | c.411A>T p.R137S | Missense Mutation (SNP) | VAF 35/101 reads (35%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.819); catalogued as COSV59869284; called by muse, mutect2, varscan2
- ARHGEF19 | c.606G>T p.M202I | Missense Mutation (SNP) | VAF 38/90 reads (42%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.027); catalogued as COSV99580712; called by muse, mutect2, varscan2
- BOD1L1 | c.3103_3105del p.K1035del | In Frame Del (DEL) | VAF 62/98 reads (63%) | catalogued as rs745595311; called by pindel, varscan2
- BPIFA3 | c.129T>G p.I43M | Missense Mutation (SNP) | VAF 95/160 reads (59%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.658); catalogued as COSV64925984; called by muse, mutect2, varscan2
- BRCA2 | c.9692C>A p.S3231* | Nonsense Mutation (SNP) | VAF 25/65 reads (38%) | catalogued as COSV101200912, COSV66337532; called by muse, mutect2, varscan2
- CACNA1A | c.3443T>G p.L1148R | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.862); catalogued as COSV64201633; called by muse, mutect2, varscan2
- CATSPERB | c.3145G>A p.E1049K | Missense Mutation (SNP) | VAF 35/49 reads (71%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.536); catalogued as rs910747411, COSV56428648, COSV99831089; called by muse, mutect2, varscan2
- CCDC178 | c.633A>C p.Q211H | Missense Mutation (SNP) | VAF 112/162 reads (69%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV100287735, COSV55757125; called by muse, mutect2, varscan2
- CD163 | c.1148C>T p.A383V | Missense Mutation (SNP) | VAF 39/95 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV63133988; called by muse, mutect2, varscan2
- CD163L1 | c.898T>C p.C300R | Missense Mutation (SNP) | VAF 44/102 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1242093471, COSV58018648; called by muse, mutect2, varscan2
- CEP250 | c.7299C>A p.S2433R | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); catalogued as COSV61171181; called by muse, mutect2, varscan2
- CFHR1 | c.728T>A p.L243H | Missense Mutation (SNP) | VAF 39/297 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100258963; called by muse, mutect2, varscan2
- CMBL | c.616A>C p.T206P | Missense Mutation (SNP) | VAF 49/128 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); catalogued as COSV56983941; called by muse, mutect2, varscan2
- CNMD | c.798A>C p.E266D | Missense Mutation (SNP) | VAF 44/140 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV60131415; called by muse, mutect2, varscan2
- CPSF1 | c.2794C>T p.R932C | Missense Mutation (SNP) | VAF 25/30 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs782361727, COSV58234136; called by muse, mutect2, varscan2
- CREM | c.983T>A p.L328H (on ENST00000429130; = p.L283H on NM_181571.3) | Missense Mutation (SNP) | VAF 37/84 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59768214; called by muse, mutect2, varscan2
- CSDE1 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 10/35 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.775); catalogued as COSV99795846; called by muse, mutect2, varscan2
- CSMD3 | c.3434T>A p.I1145N (on ENST00000297405 / NM_001363185.1; = p.I1041N on NM_052900.3) | Missense Mutation (SNP) | VAF 34/93 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV52219161; called by muse, mutect2, varscan2
- CYLC1 | c.1568A>C p.E523A | Missense Mutation (SNP) | VAF 63/186 reads (34%) | SIFT tolerated (0.22); PolyPhen benign (0.111); catalogued as COSV61413144; called by muse, mutect2, varscan2
- CYP2A6 | c.817A>T p.I273F | Missense Mutation (SNP) | VAF 63/149 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.666); catalogued as COSV56535854; called by muse, mutect2, varscan2
- DCAF10 | c.431_432insG p.N144Kfs*7 | Frame Shift Ins (INS) | VAF 30/63 reads (48%) | catalogued as COSV54289306; called by mutect2, pindel, varscan2
- DDX28 | c.1553C>T p.A518V | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60105853; called by muse, mutect2, varscan2
- DLC1 | c.518C>A p.A173E | Missense Mutation (SNP) | VAF 111/161 reads (69%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.015); catalogued as COSV52311014; called by muse, mutect2, varscan2
- DNAH7 | c.9738G>T p.E3246D | Missense Mutation (SNP) | VAF 81/202 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0.033); catalogued as COSV56771100; called by muse, mutect2, varscan2
- EPC2 | c.2272T>A p.L758I | Missense Mutation (SNP) | VAF 56/152 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as COSV51545966; called by muse, mutect2, varscan2
- ETS1 | c.1291G>A p.A431T | Missense Mutation (SNP) | VAF 58/140 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.123); catalogued as rs774575276, COSV60097292; called by muse, mutect2, varscan2
- F3 | c.529G>T p.D177Y | Missense Mutation (SNP) | VAF 100/230 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV61845184; called by muse, mutect2, varscan2
- FBF1 | c.937G>A p.A313T (on ENST00000586717; = p.A327T on NM_001319193.1) | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.114); catalogued as rs778313571, COSV59864339; called by muse, mutect2, varscan2
- FCER2 | c.943C>T p.P315S | Missense Mutation (SNP) | VAF 60/128 reads (47%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.007); catalogued as rs1377287975, COSV60916716; called by muse, mutect2, varscan2
- FOXD2 | c.712C>T p.H238Y | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.059); catalogued as COSV100599305; called by muse, varscan2
- GIMAP2 | c.725G>A p.S242N | Missense Mutation (SNP) | VAF 38/90 reads (42%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as COSV56235607; called by muse, mutect2, varscan2
- GJA8 | c.97C>T p.R33W | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587710840, COSV53787626; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GPR174 | c.628T>G p.L210V | Missense Mutation (SNP) | VAF 82/246 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0.065); catalogued as COSV52132970; called by muse, mutect2, varscan2
- GSTM2 | c.261C>T p.C87= | Splice Region (SNP) | VAF 48/127 reads (38%) | catalogued as rs778325929, COSV53983219; called by muse, mutect2, varscan2
- GUCY1A2 | c.1765A>G p.I589V | Missense Mutation (SNP) | VAF 51/125 reads (41%) | SIFT tolerated (0.05); PolyPhen benign (0.08); catalogued as rs761502300, COSV99976459; called by muse, mutect2, varscan2
- HCN1 | c.1602T>A p.D534E | Missense Mutation (SNP) | VAF 60/117 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.609); catalogued as COSV57518395; called by muse, mutect2, varscan2
- HDAC9 | c.2788G>T p.A930S | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.729); catalogued as COSV67776342; called by muse, mutect2, varscan2
- HECW1 | c.4036C>T p.R1346C | Missense Mutation (SNP) | VAF 166/268 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1304496410, COSV67832695; called by muse, mutect2, varscan2
- HS1BP3 | c.143G>A p.R48H | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as rs777489598, COSV58313576; called by muse, mutect2, varscan2
- HSPB8 | c.374A>T p.H125L | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV56138398; called by muse, mutect2, varscan2
- HYDIN | c.5579A>T p.Y1860F | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59261200; called by muse, varscan2
- HYDIN | c.5578T>A p.Y1860N | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59261218; called by muse, varscan2
- HYDIN | c.5577T>A p.F1859L | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); catalogued as COSV99993561; called by muse, varscan2
- IGFN1 | c.1631C>A p.P544H (on ENST00000295591 / NM_001367841.1; = p.P3001H on NM_001164586.2) | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV55175563; called by muse, mutect2, varscan2
- ITGA4 | c.2669G>T p.C890F | Missense Mutation (SNP) | VAF 64/165 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV67897802; called by muse, mutect2, varscan2
- ITGA8 | c.2005C>T p.H669Y | Missense Mutation (SNP) | VAF 80/201 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV100958965, COSV65226146; called by muse, mutect2, varscan2
- ITPRIPL1 | c.875C>A p.P292H (on ENST00000439118 / NM_001008949.3; = p.P300H on NM_178495.6) | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV63153862; called by muse, mutect2, varscan2
- KCNC2 | c.356G>A p.R119H | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54371719; called by muse, mutect2, varscan2
- KIF16B | c.3004A>G p.R1002G | Missense Mutation (SNP) | VAF 95/193 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.425); catalogued as COSV61708124; called by muse, mutect2, varscan2
- KYNU | c.1073G>A p.R358Q | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs377612575; called by muse, mutect2, varscan2
- LINGO4 | c.445G>T p.D149Y | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59093578, COSV59093754; called by muse, mutect2, varscan2
- LRP4 | c.5179G>A p.A1727T | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs914781633, COSV66134831; called by muse, mutect2, varscan2
- MED12 | c.688A>G p.I230V | Missense Mutation (SNP) | VAF 87/94 reads (93%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as COSV61344277; called by muse, mutect2, varscan2
- MED13 | c.4718C>G p.S1573C | Missense Mutation (SNP) | VAF 66/127 reads (52%) | SIFT tolerated (0.05); PolyPhen benign (0.241); catalogued as COSV67264499; called by muse, mutect2, varscan2
- MSTO1 | c.1174G>A p.G392R | Missense Mutation (SNP) | VAF 43/117 reads (37%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV99824363; called by muse, mutect2, varscan2
- MVK | c.317G>A p.R106H | Missense Mutation (SNP) | VAF 36/111 reads (32%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs778337320, COSV57332232; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYCBP2 | c.5417A>T p.D1806V (on ENST00000357337; = p.D1844V on NM_015057.5) | Missense Mutation (SNP) | VAF 80/234 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62025496; called by muse, mutect2, varscan2
- NALCN | c.2909G>A p.C970Y | Missense Mutation (SNP) | VAF 32/57 reads (56%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.846); catalogued as rs1305277434, COSV51931749, COSV51944323; called by muse, mutect2, varscan2
- NEU2 | c.284C>T p.T95M | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs201616110; called by muse, mutect2, varscan2
- NLRP8 | c.2360G>A p.R787Q | Missense Mutation (SNP) | VAF 28/49 reads (57%) | SIFT tolerated (1); PolyPhen benign (0.018); catalogued as rs376081039; called by muse, mutect2, varscan2
- OR5V1 | c.961T>C p.Y321H | Missense Mutation (SNP) | VAF 68/135 reads (50%) | PolyPhen benign (0.193); catalogued as COSV65828609; called by muse, mutect2, varscan2
- PCDHA13 | c.415C>T p.R139* | Nonsense Mutation (SNP) | VAF 23/65 reads (35%) | catalogued as COSV56516139; called by muse, mutect2, varscan2
- PCDHB13 | c.1520A>G p.N507S | Missense Mutation (SNP) | VAF 37/87 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.963); catalogued as rs782336970, COSV53397946; called by muse, mutect2, varscan2
- PDZD4 | c.296+1G>A p.X99_splice | Splice Site (SNP) | VAF 12/28 reads (43%) | catalogued as rs782237699, COSV51247767; called by muse, mutect2
- PEX2 | c.126T>A p.H42Q | Missense Mutation (SNP) | VAF 53/197 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV100824909; called by muse, mutect2, varscan2
- PGK2 | c.608A>C p.N203T | Missense Mutation (SNP) | VAF 69/161 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.038); catalogued as rs746884249, COSV59164376; called by muse, mutect2, varscan2
- PHIP | c.3928C>T p.R1310C | Missense Mutation (SNP) | VAF 56/149 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs369513920; called by muse, mutect2, varscan2
- PI4K2B | c.924T>G p.D308E | Missense Mutation (SNP) | VAF 108/172 reads (63%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as COSV53511875; called by muse, mutect2, varscan2
- PKHD1 | c.6388G>A p.A2130T | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.115); catalogued as COSV61882326; called by muse, mutect2, varscan2
- PLPPR1 | c.347A>G p.Y116C | Missense Mutation (SNP) | VAF 34/64 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV66454433; called by muse, mutect2, varscan2
- POP1 | c.2453G>A p.W818* | Nonsense Mutation (SNP) | VAF 26/49 reads (53%) | catalogued as COSV62893199; called by muse, mutect2, varscan2
- PRR19 | c.488G>A p.R163Q | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.579); catalogued as rs554910146, COSV56625934; called by muse, mutect2, varscan2
- PTPN4 | c.427_429del p.S143del | In Frame Del (DEL) | VAF 27/241 reads (11%) | catalogued as rs1362242851; called by mutect2, pindel, varscan2
- PTPRC | c.1117T>C p.Y373H | Missense Mutation (SNP) | VAF 168/391 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs1428550336, COSV61414402; called by muse, mutect2, varscan2
- RASA3 | c.1621T>G p.F541V | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.912); catalogued as COSV61868745; called by muse, mutect2, varscan2
- REL | c.1784G>A p.S595N | Missense Mutation (SNP) | VAF 45/134 reads (34%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.01); catalogued as rs770726535, COSV54365121; called by muse, mutect2, varscan2
- RP1 | c.904T>G p.L302V | Missense Mutation (SNP) | VAF 106/178 reads (60%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.817); catalogued as COSV55119679; called by muse, mutect2, varscan2
- SAFB | c.1285T>C p.Y429H | Missense Mutation (SNP) | VAF 54/71 reads (76%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.519); catalogued as COSV52652083; called by muse, mutect2, varscan2
- SCTR | c.521G>A p.R174H | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs748166802, COSV50026747; called by muse, mutect2, varscan2
- SLC39A12 | c.11G>A p.R4Q | Missense Mutation (SNP) | VAF 38/111 reads (34%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as rs376569179; called by muse, mutect2, varscan2
- SLX4 | c.3160T>A p.S1054T | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT tolerated (0.42); PolyPhen benign (0.009); catalogued as COSV53565313; called by muse, mutect2, varscan2
- SMAD5 | c.1171C>A p.L391I | Missense Mutation (SNP) | VAF 56/90 reads (62%) | SIFT tolerated (0.06); PolyPhen benign (0.115); catalogued as COSV72597356; called by muse, mutect2, varscan2
- SNTG2 | c.1259C>T p.T420M | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as rs1444627239, COSV57975870; called by muse, mutect2, varscan2
- SORBS1 | c.1442G>C p.S481T (on ENST00000361941 / NM_001034954.2; = p.S271T on NM_006434.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 44/72 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs749801396, COSV53359744; called by muse, mutect2, varscan2
- SPART | c.1981G>T p.A661S | Missense Mutation (SNP) | VAF 93/486 reads (19%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.015); catalogued as COSV62086369; called by muse, mutect2, varscan2
- ST6GAL1 | c.592C>G p.L198V | Missense Mutation (SNP) | VAF 14/35 reads (40%) | PolyPhen probably damaging (0.999); catalogued as COSV51471138; called by muse, mutect2, varscan2
- STX19 | c.340A>C p.K114Q | Missense Mutation (SNP) | VAF 87/194 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.273); catalogued as COSV57399133; called by muse, mutect2, varscan2
- SYNE1 | c.5909A>G p.Q1970R (on ENST00000367255 / NM_182961.4; = p.Q1977R on NM_033071.3) | Missense Mutation (SNP) | VAF 71/201 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs1174867120, COSV55017466; called by muse, mutect2, varscan2
- SYVN1 | c.652T>C p.F218L | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated (0.4); PolyPhen benign (0.006); catalogued as rs770594418, COSV53695896; called by muse, mutect2, varscan2
- TBX20 | c.860G>A p.R287Q | Missense Mutation (SNP) | VAF 68/276 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1288985415, COSV101282407, COSV68784194; called by muse, mutect2, varscan2
- TEKT5 | c.263G>A p.R88H | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs768273976, COSV51586722, COSV99295769; called by muse, mutect2, varscan2
- TERF2 | c.1336C>T p.P446S | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT tolerated (0.3); PolyPhen benign (0.185); catalogued as COSV54747968; called by muse, mutect2, varscan2
- TGFBR3 | c.391G>A p.E131K | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as COSV53021833, COSV53027388; called by muse, mutect2, varscan2
- TGM2 | c.1091A>G p.K364R | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.075); catalogued as COSV63931726; called by muse, mutect2, varscan2
- TMC3 | c.882C>G p.N294K | Missense Mutation (SNP) | VAF 40/52 reads (77%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.925); catalogued as COSV63923590; called by muse, mutect2, varscan2
- TNRC18 | c.8032T>C p.S2678P | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.905); catalogued as COSV60308147; called by muse, varscan2
- TRIM7 | c.1001G>C p.G334A | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT tolerated (0.7); PolyPhen benign (0.034); catalogued as COSV51244352; called by muse, mutect2, varscan2
- TRPM6 | c.1142T>G p.I381R | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV62512444; called by muse, mutect2, varscan2
- TTLL7 | c.761A>G p.N254S | Missense Mutation (SNP) | VAF 98/254 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99553044; called by muse, varscan2
- TTN | c.18786A>T p.K6262N (on ENST00000591111; = p.K5335N on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/55 reads (42%) | PolyPhen possibly damaging (0.553); catalogued as COSV60149626; called by muse, mutect2, varscan2
- UPF1 | c.1925G>A p.R642H (on ENST00000599848 / NM_001297549.2; = p.R631H on NM_002911.4) | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.034); catalogued as COSV53198026; called by muse, mutect2, varscan2
- USP54 | c.4757C>T p.S1586F | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs1490348417, COSV100357594; called by muse, mutect2, varscan2
- VIRMA | c.4710G>C p.E1570D | Missense Mutation (SNP) | VAF 82/268 reads (31%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.876); catalogued as COSV52586746; called by muse, mutect2, varscan2
- WEE2 | c.779T>A p.V260D | Missense Mutation (SNP) | VAF 41/97 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66879348; called by muse, mutect2, varscan2
- ZIC3 | c.739A>T p.I247F | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV54975128; called by muse, mutect2, varscan2
- ZMYND8 | c.3443A>C p.K1148T (on ENST00000311275 / NM_001363741.2; = p.K1122T on NM_012408.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/193 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.977); catalogued as COSV53690770; called by muse, mutect2, varscan2
- ZNF638 | c.1951G>C p.E651Q | Missense Mutation (SNP) | VAF 102/253 reads (40%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.986); catalogued as COSV52490168; called by muse, mutect2, varscan2
- APC | c.2544dup p.D849Rfs*2 | Frame Shift Ins (INS) | VAF 23/40 reads (58%) | called by mutect2, pindel, varscan2
- TP53 | c.321_344del p.G108_H115del | In Frame Del (DEL) | VAF 13/27 reads (48%) | called by mutect2, pindel, varscan2
- ZNF804B | c.2262dup p.R755Tfs*13 | Frame Shift Ins (INS) | VAF 30/107 reads (28%) | called by mutect2, pindel, varscan2
- ADCY4 | c.1221A>G p.R407= | Silent (SNP) | VAF 12/20 reads (60%) | catalogued as COSV60255441; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.1026C>A p.G342= | Silent (SNP) | VAF 25/119 reads (21%) | catalogued as COSV58444593; called by muse, mutect2, varscan2
- ADGRG4 | c.1884T>G p.A628= | Silent (SNP) | VAF 26/83 reads (31%) | catalogued as COSV54959699; called by muse, mutect2, varscan2
- AQR | c.843T>A p.V281= | Silent (SNP) | VAF 68/78 reads (87%) | catalogued as COSV50038142; called by muse, mutect2, varscan2
- ATP2B3 | c.3432G>A p.T1144= | Silent (SNP) | VAF 73/81 reads (90%) | catalogued as COSV54843766, COSV99685026; called by muse, mutect2, varscan2
- CHST3 | c.1128C>T p.R376= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as COSV100910518; called by muse, mutect2
- CLEC14A | c.1431T>A p.G477= | Silent (SNP) | VAF 14/22 reads (64%) | catalogued as COSV60563087; called by muse, mutect2, varscan2
- GABRQ | c.1287G>A p.S429= | Silent (SNP) | VAF 121/133 reads (91%) | catalogued as rs919456266, COSV64782575; called by muse, mutect2, varscan2
- GAPVD1 | c.2574A>G p.P858= (on ENST00000394104; = p.P885= on NM_015635.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 45/94 reads (48%) | catalogued as COSV52924434; called by muse, mutect2, varscan2
- KCNC2 | c.1317T>G p.G439= | Silent (SNP) | VAF 22/56 reads (39%) | catalogued as COSV54361394, COSV54365534; called by muse, mutect2, varscan2
- KRTAP11-1 | c.481A>C p.R161= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as COSV100190795; called by muse, mutect2, varscan2
- KRTAP5-10 | c.222T>C p.C74= | Silent (SNP) | VAF 30/85 reads (35%) | catalogued as COSV64795028; called by muse, mutect2, varscan2
- MAGEB4 | c.636C>T p.G212= | Silent (SNP) | VAF 72/135 reads (53%) | catalogued as COSV66775959; called by muse, mutect2, varscan2
- MBD5 | c.2415T>C p.N805= | Silent (SNP) | VAF 35/72 reads (49%) | catalogued as rs1207258162, COSV68695545; called by muse, mutect2, varscan2
- MRPS28 | c.79C>A p.R27= | Silent (SNP) | VAF 15/56 reads (27%) | catalogued as COSV52562069, COSV52563206; called by muse, mutect2, varscan2
- MTMR1 | c.1929C>T p.A643= | Silent (SNP) | VAF 40/48 reads (83%) | catalogued as rs782424909, COSV60936953; called by muse, mutect2, varscan2
- NBEA | c.4656G>A p.R1552= | Silent (SNP) | VAF 99/407 reads (24%) | catalogued as COSV59795887; called by muse, mutect2, varscan2
- NTSR1 | c.195G>A p.L65= | Silent (SNP) | VAF 20/97 reads (21%) | catalogued as COSV100980677, COSV65138908; called by muse, mutect2, varscan2
- RALGAPA2 | c.849T>G p.T283= | Silent (SNP) | VAF 68/154 reads (44%) | catalogued as COSV52501413; called by muse, mutect2, varscan2
- RASA3 | c.996G>A p.Q332= | Silent (SNP) | VAF 31/106 reads (29%) | catalogued as COSV61868751; called by muse, mutect2, varscan2
- RASD2 | c.432C>T p.H144= | Silent (SNP) | VAF 19/43 reads (44%) | catalogued as rs772958089, COSV53352800; called by muse, mutect2, varscan2
- RFX4 | c.1482A>G p.R494= (on ENST00000392842 / NM_213594.3; = p.R400= on NM_032491.6) | Silent (SNP) | VAF 19/123 reads (15%) | catalogued as COSV57577102; called by muse, mutect2, varscan2
- SLC32A1 | c.627G>A p.A209= | Silent (SNP) | VAF 7/89 reads (8%) | catalogued as COSV54147230; called by muse, mutect2
- SPOPL | c.561A>G p.A187= | Silent (SNP) | VAF 52/144 reads (36%) | catalogued as COSV54514246; called by muse, mutect2, varscan2
- TLR9 | c.1170G>C p.L390= | Silent (SNP) | VAF 21/36 reads (58%) | catalogued as COSV62347290; called by muse, mutect2, varscan2
- ZNF224 | c.1875A>G p.K625= | Silent (SNP) | VAF 21/61 reads (34%) | catalogued as COSV61242626; called by muse, mutect2, varscan2
- AL132655.6 | chr20:58840323 G>A | 5'Flank (SNP) | VAF 6/22 reads (27%) | catalogued as COSV58338082; called by muse, mutect2, varscan2
- CD300LD | c.-66T>A | 5'UTR (SNP) | VAF 22/60 reads (37%) | catalogued as COSV60084081; called by muse, mutect2, varscan2
- SSPOP | n.14152C>T | RNA (SNP) | VAF 23/42 reads (55%) | catalogued as rs369545096; called by muse, mutect2, varscan2
